Somatic mutation profile of tumor specimen TCGA-5P-A9KA-01A (aliquot TCGA-5P-A9KA-01A-11D-A42J-10) from TCGA case TCGA-5P-A9KA, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 61.7 years (22,545 days).
Specimen TCGA-5P-A9KA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e2738c11-9d43-4d71-88e3-05fd7610d2d2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-5P-A9KA-10A (Blood Derived Normal), aliquot TCGA-5P-A9KA-10A-01D-A42M-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1339ef74-4873-46b1-8861-fc64aa3b33f8

The open-access MAF lists 95 somatic variants for this specimen: 73 protein-altering or splice-affecting, 21 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 57, Silent 21, Frame Shift Del 6, Splice Site 5, In Frame Del 3, Splice Region 1, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MET | c.3749T>C p.M1250T | Missense Mutation (SNP) | VAF 42/129 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913245, CM992181, COSV59255872; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADGRG7 | c.575C>G p.T192S | Missense Mutation (SNP) | VAF 67/172 reads (39%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV99841247; called by muse, mutect2, varscan2
- ALPK3 | c.453G>C p.Q151H | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99361366; called by muse, mutect2
- ARID4B | c.3542G>C p.S1181T | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV99935881; called by muse, mutect2, varscan2
- ATRNL1 | c.3559G>T p.D1187Y | Missense Mutation (SNP) | VAF 46/177 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100371667; called by muse, mutect2, varscan2
- B3GAT1 | c.425C>G p.T142R | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100438071, COSV56995759; called by muse, mutect2, varscan2
- C18orf25 | c.347A>T p.E116V | Missense Mutation (SNP) | VAF 39/133 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.897); catalogued as rs1206711231, COSV99960111; called by muse, mutect2, varscan2
- C19orf57 | c.208T>C p.S70P | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.899); catalogued as COSV100694759; called by muse, mutect2
- C19orf57 | c.207-1G>A p.X69_splice | Splice Site (SNP) | VAF 31/92 reads (34%) | catalogued as COSV100694761; called by muse, mutect2
- CAND2 | c.1280T>A p.L427H (on ENST00000456430 / NM_001162499.2; = p.L334H on NM_012298.3) | Missense Mutation (SNP) | VAF 132/398 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.105); catalogued as COSV55989220, COSV99929393; called by muse, varscan2
- CCDC110 | c.1845G>C p.Q615H | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV100294053; called by muse, mutect2
- CEACAM5 | c.599T>A p.L200H | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99704019; called by muse, mutect2, varscan2
- CFAP43 | c.257A>G p.K86R | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT tolerated (0.61); PolyPhen benign (0.009); catalogued as COSV99530855; called by muse, mutect2, varscan2
- CIP2A | c.2408-1G>T p.X803_splice | Splice Site (SNP) | VAF 15/34 reads (44%) | catalogued as COSV99843013; called by muse, mutect2, varscan2
- CPSF2 | c.2256A>T p.R752S | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100102977; called by muse, mutect2, varscan2
- CRMP1 | c.969-1G>T p.X323_splice | Splice Site (SNP) | VAF 6/45 reads (13%) | catalogued as COSV100272083, COSV61479538; called by muse, mutect2, varscan2
- CTC1 | c.1702G>A p.D568N | Missense Mutation (SNP) | VAF 50/176 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.062); catalogued as COSV59853515; called by muse, mutect2, varscan2
- CTTNBP2 | c.3690A>T p.G1230= | Splice Region (SNP) | VAF 58/182 reads (32%) | catalogued as COSV99354329; called by muse, mutect2, varscan2
- CUL3 | c.1108A>T p.I370F | Missense Mutation (SNP) | VAF 84/263 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.415); catalogued as COSV100024443; called by muse, mutect2, varscan2
- CYP2C19 | c.1306G>A p.V436M | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.204); catalogued as COSV100990564; called by muse, mutect2
- ECH1 | c.272A>C p.E91A | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.413); catalogued as COSV99669620; called by muse, mutect2, varscan2
- EMILIN3 | c.1243C>A p.P415T | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.59); PolyPhen benign (0.006); catalogued as COSV100182675; called by muse, mutect2, varscan2
- FBXL4 | c.389C>T p.T130I | Missense Mutation (SNP) | VAF 39/119 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.03); catalogued as COSV100014226; called by muse, mutect2, varscan2
- GFI1B | c.437C>T p.T146I | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as COSV100254315; called by muse, mutect2, varscan2
- HYAL2 | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1346655486, COSV51700899; called by muse, mutect2, varscan2
- IGHMBP2 | c.1937T>G p.I646S | Missense Mutation (SNP) | VAF 39/123 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as COSV99662253; called by muse, mutect2, varscan2
- ITGB5 | c.1165C>A p.Q389K | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT tolerated (0.94); PolyPhen benign (0.08); catalogued as COSV99950871; called by muse, mutect2, varscan2
- ITPR1 | c.1535A>G p.E512G (on ENST00000354582; = p.E497G on NM_002222.7) | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100232128; called by muse, mutect2
- KIAA0319 | c.2953A>C p.K985Q | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100985667; called by muse, mutect2, varscan2
- KMT2C | c.7249C>A p.P2417T | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV100073873; called by muse, mutect2, varscan2
- MYH8 | c.4606G>T p.V1536L | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV101238485, COSV67967965; called by muse, mutect2, varscan2
- PCDH12 | c.2919A>T p.Q973H | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99190854; called by muse, mutect2, varscan2
- PCDHA7 | c.1870G>A p.V624M | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV65348271; called by muse, mutect2, varscan2
- PHLPP1 | c.4774G>T p.D1592Y | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV99408650; called by muse, mutect2, varscan2
- PLA2G4A | c.440G>A p.S147N | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as COSV100820608, COSV66557022; called by muse, mutect2, varscan2
- PPP2R5A | c.1433G>C p.S478T | Missense Mutation (SNP) | VAF 64/585 reads (11%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.007); catalogued as COSV99801324; called by muse, mutect2, varscan2
- PPP5C | c.857T>A p.L286H | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99183519; called by muse, mutect2, varscan2
- PRAMEF19 | c.904del p.Y302Mfs*4 | Frame Shift Del (DEL) | VAF 129/461 reads (28%) | catalogued as rs1171136498; called by mutect2, pindel, varscan2
- PTPRB | c.1749A>C p.E583D | Missense Mutation (SNP) | VAF 73/155 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99718005; called by muse, mutect2, varscan2
- QSER1 | c.2659A>G p.K887E (on ENST00000399302; = p.K1016E on NM_001076786.3) | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1203257921, COSV101234895; called by muse, mutect2
- QSER1 | c.2661A>T p.K887N (on ENST00000399302; = p.K1016N on NM_001076786.3) | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101234896; called by muse, mutect2
- RETREG2 | c.450C>G p.H150Q | Missense Mutation (SNP) | VAF 45/134 reads (34%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.76); catalogued as COSV99811609; called by muse, mutect2, varscan2
- RNF26 | c.736C>A p.H246N | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (1); PolyPhen possibly damaging (0.847); catalogued as COSV100264872; called by muse, mutect2, varscan2
- SDCBP2 | c.434G>T p.G145V (on ENST00000339987 / NM_001199784.1; = p.G60V on NM_015685.5) | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100378271; called by muse, mutect2, varscan2
- SLC13A1 | c.84C>G p.I28M | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.389); catalogued as COSV99521167; called by muse, mutect2, varscan2
- SPAG5 | c.2806T>G p.S936A | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV99881899; called by muse, mutect2, varscan2
- SYMPK | c.2792-1G>A p.X931_splice | Splice Site (SNP) | VAF 13/38 reads (34%) | catalogued as COSV55613043, COSV99841876; called by muse, mutect2, varscan2
- SYNE1 | c.20985A>C p.Q6995H (on ENST00000367255 / NM_182961.4; = p.Q6924H on NM_033071.3) | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0.332); catalogued as COSV99570737; called by muse, mutect2, varscan2
- SZT2 | c.4932C>A p.S1644R (on ENST00000634258 / NM_001365999.1; = p.S1587R on NM_015284.4) | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100987465; called by muse, mutect2, varscan2
- TECPR1 | c.1999del p.V667Wfs*8 | Frame Shift Del (DEL) | VAF 7/61 reads (11%) | catalogued as COSV101130653; called by mutect2, pindel, varscan2
- TEX55 | c.220G>C p.G74R | Missense Mutation (SNP) | VAF 69/159 reads (43%) | SIFT tolerated (0.76); PolyPhen benign (0.044); catalogued as COSV99817633; called by muse, mutect2, varscan2
- TPP2 | c.1751G>A p.S584N | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as rs909553322, COSV101060337; called by muse, mutect2, varscan2
- TRIP12 | c.4132G>A p.D1378N | Missense Mutation (SNP) | VAF 44/148 reads (30%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.758); catalogued as COSV99390611; called by muse, mutect2, varscan2
- TSPYL4 | c.664G>T p.D222Y | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100126947; called by muse, mutect2, varscan2
- TST | c.639C>A p.F213L | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.87); catalogued as COSV99968211; called by muse, mutect2, varscan2
- TUBE1 | c.1292A>G p.Q431R | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.027); catalogued as COSV100037104; called by muse, mutect2, varscan2
- VAV1 | c.2384C>T p.A795V | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100409240; called by muse, mutect2, varscan2
- VOPP1 | c.218T>C p.F73S | Missense Mutation (SNP) | VAF 34/140 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99567375; called by muse, mutect2, varscan2
- WEE1 | c.287C>A p.P96H | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.07); catalogued as rs1446188482, COSV100219773; called by muse, mutect2
- ZBTB5 | c.449G>A p.G150E | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100312840; called by muse, mutect2, varscan2
- ZDBF2 | c.1311T>G p.D437E | Missense Mutation (SNP) | VAF 7/92 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.076); catalogued as COSV100985112; called by muse, mutect2
- ZIC5 | c.133G>C p.A45P | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV99940653; called by muse, mutect2, varscan2
- ZNF572 | c.322C>A p.H108N | Missense Mutation (SNP) | VAF 44/152 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.025); catalogued as COSV100074021; called by muse, mutect2, varscan2
- ZNF713 | c.509A>C p.N170T (on ENST00000633730 / NM_001366796.2; = p.N183T on NM_182633.3) | Missense Mutation (SNP) | VAF 46/174 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV101448744; called by muse, mutect2, varscan2
- DSCAML1 | c.3259_3282del p.R1087_N1094del (on ENST00000321322; = p.R1027_N1034del on NM_020693.4) | In Frame Del (DEL) | VAF 26/103 reads (25%) | called by mutect2, pindel, varscan2
- JAZF1 | c.664del p.L222Cfs*55 | Frame Shift Del (DEL) | VAF 18/75 reads (24%) | called by mutect2, pindel, varscan2
- KMT2C | c.3494_3496del p.E1165_L1166delinsV | In Frame Del (DEL) | VAF 51/168 reads (30%) | called by mutect2, pindel, varscan2
- PEX5 | c.551+1_551+3del p.X184_splice | Splice Site (DEL) | VAF 10/55 reads (18%) | called by mutect2, pindel, varscan2
- PTGES | c.259_261del p.F87del | In Frame Del (DEL) | VAF 64/217 reads (29%) | called by mutect2, pindel, varscan2
- TBX21 | c.1588del p.Y530Ifs*11 | Frame Shift Del (DEL) | VAF 14/51 reads (27%) | called by mutect2, pindel, varscan2
- TLN2 | c.6924dup p.E2309Rfs*14 | Frame Shift Ins (INS) | VAF 21/89 reads (24%) | called by mutect2, pindel, varscan2
- TRAPPC6B | c.173del p.F58Sfs*5 | Frame Shift Del (DEL) | VAF 26/70 reads (37%) | called by mutect2, pindel, varscan2
- USP43 | c.564del p.E188Dfs*46 | Frame Shift Del (DEL) | VAF 40/149 reads (27%) | called by mutect2, pindel, varscan2
- CCR9 | c.967A>C p.R323= (on ENST00000357632 / NM_031200.3; = p.R311= on NM_006641.4) | Silent (SNP) | VAF 30/89 reads (34%) | catalogued as COSV100591720; called by muse, mutect2, varscan2
- DDX41 | c.315C>G p.A105= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as COSV100286681; called by muse, varscan2
- HACD4 | c.516T>C p.P172= | Silent (SNP) | VAF 49/153 reads (32%) | catalogued as rs750789873, COSV101530610; called by muse, mutect2, varscan2
- ISYNA1 | c.1671C>A p.T557= | Silent (SNP) | VAF 28/82 reads (34%) | catalogued as COSV99526183; called by muse, mutect2, varscan2
- KNTC1 | c.999C>A p.L333= | Silent (SNP) | VAF 51/115 reads (44%) | catalogued as COSV100338509; called by muse, mutect2, varscan2
- LAMA3 | c.1164G>T p.G388= | Silent (SNP) | VAF 22/78 reads (28%) | catalogued as COSV100557129, COSV58073520; called by muse, mutect2, varscan2
- LRBA | c.177A>G p.E59= | Silent (SNP) | VAF 38/142 reads (27%) | catalogued as COSV100841881; called by muse, mutect2, varscan2
- MAP3K10 | c.2841G>C p.L947= | Silent (SNP) | VAF 36/114 reads (32%) | catalogued as COSV99454583; called by muse, mutect2, varscan2
- NLRC4 | c.2586A>G p.K862= | Silent (SNP) | VAF 5/58 reads (9%) | catalogued as COSV100707446; called by muse, mutect2
- NOL6 | c.1569C>T p.N523= | Silent (SNP) | VAF 20/63 reads (32%) | catalogued as rs1360946080, COSV99954916; called by muse, mutect2, varscan2
- PTPRZ1 | c.483C>T p.D161= | Silent (SNP) | VAF 25/71 reads (35%) | catalogued as rs773885417, COSV101100415; called by muse, mutect2, varscan2
- SESN1 | c.609A>C p.V203= (on ENST00000356644 / NM_001199933.1; = p.V262= on NM_014454.3) | Silent (SNP) | VAF 30/117 reads (26%) | catalogued as COSV100122806; called by muse, mutect2, varscan2
- SHPRH | c.2463T>A p.A821= | Silent (SNP) | VAF 21/55 reads (38%) | catalogued as COSV99262333; called by muse, mutect2, varscan2
- SIDT2 | c.2274C>T p.V758= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as COSV99638026; called by muse, mutect2, varscan2
- SLC5A3 | c.990C>T p.C330= | Silent (SNP) | VAF 5/57 reads (9%) | called by muse, mutect2
- SYNE2 | c.6699T>C p.L2233= | Silent (SNP) | VAF 52/149 reads (35%) | catalogued as COSV100648070; called by muse, mutect2, varscan2
- TRIP12 | c.4131A>T p.T1377= | Silent (SNP) | VAF 42/147 reads (29%) | catalogued as COSV99390614; called by muse, mutect2, varscan2
- TSC2 | c.1380C>G p.A460= | Silent (SNP) | VAF 14/61 reads (23%) | catalogued as COSV99554672; called by muse, mutect2, varscan2
- ZFHX3 | c.2595C>T p.Y865= | Silent (SNP) | VAF 24/69 reads (35%) | catalogued as COSV51738319, COSV99213567; called by muse, mutect2, varscan2
- ZIC5 | c.132G>A p.T44= | Silent (SNP) | VAF 15/64 reads (23%) | catalogued as COSV99940655; called by muse, mutect2, varscan2
- ZNF536 | c.1138C>A p.R380= | Silent (SNP) | VAF 23/77 reads (30%) | catalogued as COSV100835449, COSV62830708; called by muse, mutect2, varscan2
- AL136982.4 | n.464G>C | RNA (SNP) | VAF 39/107 reads (36%) | called by muse, mutect2, varscan2
